Gene-level copy-number profile of tumor specimen TCGA-AC-A23H-01A from TCGA case TCGA-AC-A23H, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AC-A23H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.f8597ba1-42d8-4506-a306-3e443b82018d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A23H-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c54a7135-f527-4d88-bf12-8508a3a864ff

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 861; copy number 2: 4,956; copy number 3: 14,906; copy number 4: 15,264; copy number 5: 16,554; copy number 6: 4,927; copy number 7: 1,537; copy number 8: 198; copy number 9: 143; copy number 10: 46; copy number 11: 32; copy number 12: 5; copy number 15: 49; copy number 16: 171; copy number 17: 67; copy number 21: 69; copy number 25: 2; copy number 26: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A23H-01A-11D-A160-01): tumor purity 0.67, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 418 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:1,540,321–2,229,241, 6 genes, copy number 11: AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P.
- chr11:68,980,021–69,704,022, 23 genes, copy number 26: MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19.
- chr11:70,014,858–71,639,769, 47 genes, copy number 21: AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6, OR7E4P, AP000867.3, AP000867.4.
- chr17:39,461,486–39,944,734, 22 genes, copy number 21 (within-gene range 2–21): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C.
- chr17:46,029,916–46,225,389, 1 gene, copy number 25 (within-gene range 2–25): KANSL1.
- chr17:46,193,576–46,196,723, 1 gene, copy number 25: KANSL1-AS1.
- chr17:47,694,081–48,817,214, 67 genes, copy number 17 (within-gene range 6–17) (broad region; genes not listed).
- chr17:50,375,059–52,160,017, 51 genes, copy number 11–15 (within-gene range 4–15): LRRC59, Y_RNA, AC004707.1, ACSF2, MRPS21P9, CHAD, AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1.
- chr17:52,985,513–53,106,358, 2 genes, copy number 12: LINC02876, MTCO1P40.
- chr17:53,353,427–53,439,721, 3 genes, copy number 12: AC005341.1, AC090079.1, AC090079.2.
- chr17:54,477,796–61,413,280, 195 genes, copy number 11–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 861. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
